Gene-level copy-number profile of tumor specimen TCGA-AA-3858-01A from TCGA case TCGA-AA-3858, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 67.9 years (24,806 days).
Specimen TCGA-AA-3858-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.2132f97f-137c-496e-a513-89df789eace8.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AA-3858-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/133cb181-a38d-4a79-a02a-7038d565ea1f

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 350; copy number 2: 6,385; copy number 3: 2,158; copy number 4: 38,301; copy number 5: 3,376; copy number 6: 4,439; copy number 7: 1,791; copy number 8: 2,991; copy number 9: 4; copy number 10: 2; copy number 13: 22.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AA-3858-01A-01D-0903-01): tumor purity 0.6, ploidy 4.27, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 28 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:37,784,191–37,899,497, 4 genes, copy number 9 (within-gene range 3–9): ADGRA2, BRF2, RAB11FIP1, AC130304.1.
- chr8:38,269,704–38,382,272, 1 gene, copy number 13 (within-gene range 7–13): NSD3.
- chr8:38,335,981–39,105,445, 21 genes, copy number 13 (within-gene range 7–13): AC087362.1, AC087623.2, LETM2, FGFR1, AC087623.3, AC087623.1, RPS20P22, C8orf86, AC069120.1, RNF5P1, AC016813.1, TACC1, Y_RNA, AC067817.1, AC067817.2, PLEKHA2, AC108863.1, HTRA4, TM2D2, ADAM9, SNORD38D.
- chr19:24,146,701–24,163,425, 2 genes, copy number 10: AC073534.2, AC073534.1.

Autosomal genes at a single copy (total copy number 1): 350. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
